Gene-level copy-number profile of tumor specimen MP2PRT-PAUAYD-TMP1-A from MP2PRT case MP2PRT-PAUAYD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,634 days).
Specimen MP2PRT-PAUAYD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e16fde72-7ffb-48c7-9a4d-8bdb38837364.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUAYD-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,260 have no estimate.
https://portal.gdc.cancer.gov/files/90d62428-1c32-4713-8a5e-c650e40f1843

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 151; copy number 1: 48; copy number 2: 1,295; copy number 3: 590; copy number 4: 54,291; copy number 5: 884; copy number 6: 1,104.

Homozygous deletions (total copy number 0; autosomes only): 151 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,159,751–89,192,752, 5 genes (within-gene range 0–2): IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr2:89,244,781–89,254,015, 3 genes (within-gene range 0–2): IGKV2-30, IGKV3-31, IGKV1-32.
- chr14:22,415,362–22,486,296, 21 genes (within-gene range 0–4): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52.
- chr14:105,672,308–106,481,706, 115 genes (within-gene range 0–4) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes: IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–2): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 48. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
